FM case AD6402 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/deaed77c-6b8d-4cdc-bcfc-890e8eed665e

Female, 52.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
